Gene-level copy-number profile of tumor specimen TCGA-R6-A6Y2-01B from TCGA case TCGA-R6-A6Y2, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 71.0 years (25,940 days).
Specimen TCGA-R6-A6Y2-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.f0fb7579-4028-4a35-8c79-c779fc75f411.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6Y2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae13e327-0437-42ec-b2d0-6a3ad460c71d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 874; copy number 1: 18,534; copy number 2: 38,212; copy number 3: 1,983; copy number 4: 50; copy number 5: 621.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6Y2-01B-11D-A33D-01): tumor purity 0.48, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,623,806–2,245,605, 1 gene (within-gene range 0–2): GMDS.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr16:78,525,189–78,796,362, 4 genes: AC046158.4, AC046158.2, AC046158.3, AC009141.1.
- chr21:29,496,047–29,500,386, 1 gene: BACH1-IT3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 621 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–73,714,527, 336 genes, copy number 5 (broad region; genes not listed).
- chr15:89,305,198–101,086,066, 285 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,463. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
